Gene-level copy-number profile of tumor specimen TCGA-4Z-AA81-01A from TCGA case TCGA-4Z-AA81, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 80.6 years (29,457 days).
Specimen TCGA-4Z-AA81-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.8279e3d9-abaa-42a4-9804-f0eb68b13638.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4Z-AA81-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/be8ceed7-5ab0-465e-b5b2-717fd27bafa5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 106; copy number 2: 10,138; copy number 3: 25,829; copy number 4: 17,243; copy number 5: 2,584; copy number 6: 2,630; copy number 7: 52; copy number 8: 566; copy number 9: 444; copy number 11: 4; copy number 13: 14; copy number 15: 82; copy number 16: 57; copy number 18: 23; copy number 21: 9; copy number 23: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4Z-AA81-01A-11D-A390-01): tumor purity 0.55, ploidy 3.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,286 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,235,475–35,796,550, 1 gene, copy number 9 (within-gene range 2–9): UNC5D.
- chr8:35,525,176–35,707,734, 2 genes, copy number 9: LSM12P1, AC105230.1.
- chr8:36,378,069–36,779,209, 3 genes, copy number 11 (within-gene range 5–11): AC090809.1, RPL23P10, RNA5SP264.
- chr8:36,795,255–36,795,862, 1 gene, copy number 11: AC124076.1.
- chr12:630,858–990,053, 6 genes, copy number 9 (within-gene range 6–9): NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52.
- chr12:6,976,185–38,909,592, 655 genes, copy number 9–23 (within-gene range 6–23) (broad region; genes not listed).
- chr12:39,087,347–41,072,415, 23 genes, copy number 7: LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1.
- chr12:41,409,467–42,717,120, 29 genes, copy number 7: AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450.
- chr13:68,634,190–114,337,626, 566 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 104. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
